Somatic mutation profile of tumor specimen TCGA-OR-A5JT-01A (aliquot TCGA-OR-A5JT-01A-11D-A29I-10) from TCGA case TCGA-OR-A5JT, project TCGA-ACC (Adrenocortical Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Adrenal cortical carcinoma; Tissue or organ of origin: Cortex of adrenal gland; Age at diagnosis: 65.1 years (23,794 days).
Specimen TCGA-OR-A5JT-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) c405577b-662f-42a3-b6be-1e563a054652.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-OR-A5JT-10A (Blood Derived Normal), aliquot TCGA-OR-A5JT-10A-01D-A29L-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/4af7fceb-17ec-4f2a-8d51-c6fe18e0b13b

The open-access MAF lists 28 somatic variants for this specimen: 19 protein-altering or splice-affecting, 8 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 14, Silent 8, Frame Shift Ins 1, Nonstop Mutation 1, Intron 1, Splice Region 1, Frame Shift Del 1, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CLPTM1L | c.873C>G p.F291L | Missense Mutation (SNP) | VAF 12/56 reads (21%) | SIFT tolerated (0.22); PolyPhen benign (0.409); catalogued as COSV100306987; called by muse, varscan2
- MTHFD2L | c.515A>G p.H172R (on ENST00000395759 / NM_001144978.2; = p.H114R on NM_001004346.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 28/81 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs1441512205; called by muse, varscan2
- SLC6A7 | c.1745C>T p.S582L | Missense Mutation (SNP) | VAF 190/424 reads (45%) | SIFT tolerated (0.6); PolyPhen benign (0.038); catalogued as rs764057109; called by muse, mutect2, varscan2
- TBC1D9B | c.3250G>A p.D1084N (on ENST00000356834 / NM_198868.3; = p.D1067N on NM_015043.4) | Missense Mutation (SNP) | VAF 23/90 reads (26%) | SIFT tolerated (0.26); PolyPhen benign (0); catalogued as COSV100783678; called by muse, mutect2, varscan2
- TMEM74 | c.719C>T p.T240M | Missense Mutation (SNP) | VAF 29/100 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52464262; called by muse, mutect2, varscan2
- ACACB | c.1546_1547del p.L516Vfs*16 | Frame Shift Del (DEL) | VAF 22/107 reads (21%) | called by pindel, varscan2
- ALDH8A1 | c.1312C>A p.L438M | Missense Mutation (SNP) | VAF 52/128 reads (41%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.983); called by muse, mutect2, varscan2
- CACNA1H | c.2100C>A p.C700* | Nonsense Mutation (SNP) | VAF 58/121 reads (48%) | called by muse, mutect2, varscan2
- CSDE1 | c.2342dup p.N781Kfs*18 (on ENST00000358528 / NM_001007553.3; = p.N750Kfs*18 on NM_007158.6) | Frame Shift Ins (INS) | VAF 31/85 reads (36%) | called by mutect2, pindel, varscan2
- GCM1 | c.124A>C p.K42Q | Missense Mutation (SNP) | VAF 121/139 reads (87%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); called by muse, mutect2, varscan2
- GNS | c.205A>G p.K69E | Missense Mutation (SNP) | VAF 9/43 reads (21%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.501); called by muse, mutect2, varscan2
- GSTK1 | c.387T>C p.N129= | Splice Region (SNP) | VAF 15/47 reads (32%) | called by muse, mutect2, varscan2
- POMP | c.217C>G p.L73V | Missense Mutation (SNP) | VAF 32/62 reads (52%) | SIFT deleterious (0); PolyPhen possibly damaging (0.731); called by muse, mutect2, varscan2
- SSH1 | c.1981C>T p.P661S | Missense Mutation (SNP) | VAF 45/91 reads (49%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- TRAM1L1 | c.1109A>T p.*370Lext*6 | Nonstop Mutation (SNP) | VAF 17/45 reads (38%) | called by muse, mutect2, varscan2
- VAT1L | c.1025A>T p.Y342F | Missense Mutation (SNP) | VAF 7/69 reads (10%) | SIFT tolerated (0.12); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- VIP | c.355C>T p.P119S | Missense Mutation (SNP) | VAF 12/45 reads (27%) | SIFT tolerated (0.52); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- WDFY3 | c.10517G>A p.C3506Y | Missense Mutation (SNP) | VAF 45/89 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- XPC | c.656A>G p.Y219C | Missense Mutation (SNP) | VAF 25/103 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.963); called by muse, mutect2, varscan2
- ARAP1 | c.2238C>T p.H746= (on ENST00000393609 / NM_001040118.2; = p.H501= on NM_015242.4) | Silent (SNP) | VAF 28/68 reads (41%) | catalogued as rs1029972875; called by muse, mutect2, varscan2
- DYRK2 | c.735C>T p.H245= (on ENST00000344096 / NM_006482.3; = p.H172= on NM_003583.4) | Silent (SNP) | VAF 19/77 reads (25%) | called by muse, mutect2, varscan2
- KCNA1 | c.435C>A p.P145= | Silent (SNP) | VAF 40/107 reads (37%) | called by muse, mutect2, varscan2
- OR5L1 | c.297G>A p.V99= | Silent (SNP) | VAF 88/150 reads (59%) | catalogued as COSV61733790, COSV61735619; called by muse, varscan2
- PCDHB4 | c.1614G>A p.P538= | Silent (SNP) | VAF 57/593 reads (10%) | called by muse, mutect2, varscan2
- PSD2 | c.1056T>C p.S352= | Silent (SNP) | VAF 28/127 reads (22%) | called by muse, mutect2, varscan2
- SARM1 | c.2130C>A p.G710= | Silent (SNP) | VAF 16/38 reads (42%) | catalogued as COSV99135033; called by muse, mutect2, varscan2
- SLC18A2 | c.330G>A p.A110= | Silent (SNP) | VAF 38/113 reads (34%) | catalogued as rs756991714; called by muse, mutect2, varscan2
- LLCFC1 | c.158-28C>G | Intron (SNP) | VAF 30/57 reads (53%) | catalogued as rs753857670, COSV62338016; called by muse, mutect2, varscan2
